Somatic mutation profile of tumor specimen 0DSW9Y from CCDI case PBCHZX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.7 years (611 days).
Specimen 0DSW9Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d74d9230-199b-4b04-868e-e2b50d13bd0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSW9H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a25a0b48-03a0-4b6e-a573-4d07e6b26971

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Del 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1M2 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 111/533 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as rs1320068039; called by muse, mutect2, varscan2
- CCDC116 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs934117224; called by muse, mutect2, varscan2
- PRKCB | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 40/469 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57766972, COSV57792894; called by muse, mutect2
- RUVBL2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 31/376 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1480679108, COSV55485712; called by muse, mutect2
- CYP17A1 | c.934_950del p.K312Pfs*16 | Frame Shift Del (DEL) | VAF 56/493 reads (11%) | called by mutect2, pindel, varscan2
- HYAL4 | c.671A>T p.H224L | Missense Mutation (SNP) | VAF 40/675 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- OR6B3 | c.451A>G p.S151G | Missense Mutation (SNP) | VAF 12/636 reads (2%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.673); called by muse, mutect2
- PDLIM7 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, varscan2
- PDLIM7 | c.801_805del p.G268Afs*40 | Frame Shift Del (DEL) | VAF 63/332 reads (19%) | called by pindel, varscan2
- PPP1R26 | c.972C>G p.P324= | Silent (SNP) | VAF 93/324 reads (29%) | catalogued as COSV63357746; called by muse, mutect2, varscan2
- MMAB | c.519+99G>A | Intron (SNP) | VAF 13/47 reads (28%) | catalogued as rs751997838; called by muse, mutect2, varscan2
